MMRF case MMRF_1423 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/6e327cc5-9247-4118-9d7b-9bb958f6bd64

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 63 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 63.1 years (23,040 days); ISS stage: II; Days to last known disease status: 1,362 days (3.7 years); Days to last follow up: 1,362 days (3.7 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 28 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 99 days; Days to treatment end: 99 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 99 days; Days to treatment end: 99 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -14 (ECOG 0): M Protein 3.67 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 12 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 737 mg/dL; Immunoglobulin G 3.64 g/L; Immunoglobulin A 53.3 g/L; Immunoglobulin M 0.18 g/L; Beta 2 Microglobulin 3.79 µg/mL; Lactate Dehydrogenase 1.77 µkat/L; Hemoglobin 5.58 mmol/L; Leukocytes 9.6 ×10⁹/L; Absolute Neutrophil 6.5 ×10⁹/L; Platelets 344 ×10⁹/L; Creatinine 89.3 µmol/L; Blood Urea Nitrogen 8.93 mmol/L; Calcium 2.3 mmol/L; Albumin 37 g/L; Total Protein 10.6 g/dL; Glucose 8.69 mmol/L.
- Day 93 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.05 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.16 mg/dL; Immunoglobulin G 5.47 g/L; Immunoglobulin A 1.23 g/L; Immunoglobulin M 0.22 g/L; Beta 2 Microglobulin 2.05 µg/mL; Lactate Dehydrogenase 4.98 µkat/L; Hemoglobin 6.82 mmol/L; Leukocytes 11.5 ×10⁹/L; Absolute Neutrophil 9.1 ×10⁹/L; Platelets 219 ×10⁹/L; Creatinine 76 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.28 mmol/L; Albumin 45 g/L; Total Protein 6.7 g/dL; Glucose 9.13 mmol/L.
- Day 156: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.12 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.07 mg/dL; Immunoglobulin G 3.1 g/L; Immunoglobulin A 3.46 g/L; Immunoglobulin M 0.23 g/L; Beta 2 Microglobulin 2.61 µg/mL; Lactate Dehydrogenase 7.02 µkat/L; Hemoglobin 6.94 mmol/L; Leukocytes 9.7 ×10⁹/L; Absolute Neutrophil 7.6 ×10⁹/L; Platelets 303 ×10⁹/L; Creatinine 91.1 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.48 mmol/L; Albumin 44 g/L; Total Protein 6.6 g/dL; Glucose 7.7 mmol/L.
- Day 261 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.83 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.69 mg/dL; Immunoglobulin G 2.42 g/L; Immunoglobulin A 2.39 g/L; Immunoglobulin M 0.13 g/L; Beta 2 Microglobulin 2.73 µg/mL; Lactate Dehydrogenase 6.53 µkat/L; Hemoglobin 7.01 mmol/L; Leukocytes 10 ×10⁹/L; Absolute Neutrophil 8.2 ×10⁹/L; Platelets 293 ×10⁹/L; Creatinine 84 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.45 mmol/L; Albumin 43 g/L; Total Protein 6.8 g/dL; Glucose 7.7 mmol/L.
- Day 374 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.89 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.12 mg/dL; Immunoglobulin G 4.67 g/L; Immunoglobulin A 2.14 g/L; Immunoglobulin M 0.19 g/L; Beta 2 Microglobulin 2.45 µg/mL; Lactate Dehydrogenase 2.48 µkat/L; Hemoglobin 6.57 mmol/L; Leukocytes 9.7 ×10⁹/L; Absolute Neutrophil 7.5 ×10⁹/L; Platelets 316 ×10⁹/L; Creatinine 89.3 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.5 mmol/L; Albumin 44 g/L; Total Protein 6.9 g/dL; Glucose 13.8 mmol/L.
- Day 416 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.01 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.891 mg/dL; Immunoglobulin G 4.55 g/L; Immunoglobulin A 1.89 g/L; Immunoglobulin M 0.19 g/L; Lactate Dehydrogenase 2.9 µkat/L; Hemoglobin 7.69 mmol/L; Leukocytes 13.3 ×10⁹/L; Absolute Neutrophil 10.8 ×10⁹/L; Platelets 369 ×10⁹/L; Creatinine 122 µmol/L; Blood Urea Nitrogen 9.28 mmol/L; Calcium 2.43 mmol/L; Albumin 45 g/L; Total Protein 6.2 g/dL; Glucose 7.7 mmol/L.
- Day 556 (ECOG 1): M Protein 0.13 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.79 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.45 mg/dL; Immunoglobulin G 5.2 g/L; Immunoglobulin A 2.5 g/L; Immunoglobulin M 0.79 g/L; Lactate Dehydrogenase 3.32 µkat/L; Hemoglobin 7.19 mmol/L; Leukocytes 11.4 ×10⁹/L; Absolute Neutrophil 8.8 ×10⁹/L; Platelets 316 ×10⁹/L; Creatinine 111 µmol/L; Blood Urea Nitrogen 10.7 mmol/L; Calcium 2.43 mmol/L; Albumin 43 g/L; Total Protein 7.1 g/dL; Glucose 13.5 mmol/L.
- Day 637 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.83 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.78 mg/dL; Immunoglobulin G 6.39 g/L; Immunoglobulin A 2.7 g/L; Immunoglobulin M 0.4 g/L; Beta 2 Microglobulin 3.41 µg/mL; Lactate Dehydrogenase 2.65 µkat/L; Hemoglobin 7.56 mmol/L; Leukocytes 13.8 ×10⁹/L; Absolute Neutrophil 11 ×10⁹/L; Platelets 352 ×10⁹/L; Creatinine 103 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.48 mmol/L; Albumin 46 g/L; Total Protein 7.3 g/dL; Glucose 10.6 mmol/L.
- Day 739 (ECOG 2): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.43 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.38 mg/dL; Immunoglobulin G 5.95 g/L; Immunoglobulin A 2.2 g/L; Immunoglobulin M 0.41 g/L; Hemoglobin 7.75 mmol/L; Leukocytes 14.8 ×10⁹/L; Absolute Neutrophil 11.9 ×10⁹/L; Platelets 337 ×10⁹/L; Creatinine 122 µmol/L; Blood Urea Nitrogen 11.1 mmol/L; Calcium 2.35 mmol/L; Albumin 45 g/L; Total Protein 7 g/dL; Glucose 4.35 mmol/L.
- Day 835 (ECOG 2): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.68 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.55 mg/dL; Immunoglobulin G 6.89 g/L; Immunoglobulin A 2.53 g/L; Immunoglobulin M 0.57 g/L; Lactate Dehydrogenase 2.45 µkat/L; Hemoglobin 6.51 mmol/L; Leukocytes 15.7 ×10⁹/L; Absolute Neutrophil 13 ×10⁹/L; Platelets 326 ×10⁹/L; Creatinine 145 µmol/L; Blood Urea Nitrogen 16.4 mmol/L; Calcium 2.3 mmol/L; Albumin 42 g/L; Total Protein 7.2 g/dL; Glucose 6 mmol/L.
- Day 907 (ECOG 2): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.67 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.51 mg/dL; Immunoglobulin G 9.11 g/L; Immunoglobulin A 2.91 g/L; Immunoglobulin M 0.76 g/L; Beta 2 Microglobulin 3.62 µg/mL; Lactate Dehydrogenase 2.6 µkat/L; Hemoglobin 7.63 mmol/L; Leukocytes 10 ×10⁹/L; Absolute Neutrophil 7.8 ×10⁹/L; Platelets 292 ×10⁹/L; Creatinine 119 µmol/L; Blood Urea Nitrogen 9.28 mmol/L; Calcium 2.6 mmol/L; Albumin 48 g/L; Total Protein 7.8 g/dL; Glucose 11.7 mmol/L.
- Day 998 (ECOG 2): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.27 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.1 mg/dL; Immunoglobulin G 8.6 g/L; Immunoglobulin A 3.16 g/L; Immunoglobulin M 0.78 g/L; Lactate Dehydrogenase 2.48 µkat/L; Hemoglobin 7.56 mmol/L; Leukocytes 11.9 ×10⁹/L; Absolute Neutrophil 9.3 ×10⁹/L; Platelets 306 ×10⁹/L; Creatinine 131 µmol/L; Blood Urea Nitrogen 10.7 mmol/L; Calcium 2.53 mmol/L; Albumin 46 g/L; Total Protein 7.7 g/dL; Glucose 7.87 mmol/L.
- Day 1,103 (ECOG 2): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.35 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.11 mg/dL; Immunoglobulin G 8.22 g/L; Immunoglobulin A 3.14 g/L; Immunoglobulin M 0.97 g/L; Lactate Dehydrogenase 2.28 µkat/L; Hemoglobin 7.81 mmol/L; Leukocytes 13.3 ×10⁹/L; Absolute Neutrophil 10.8 ×10⁹/L; Platelets 296 ×10⁹/L; Creatinine 120 µmol/L; Blood Urea Nitrogen 11.1 mmol/L; Calcium 2.35 mmol/L; Albumin 43 g/L; Total Protein 7.3 g/dL; Glucose 12.5 mmol/L.
- Day 1,187 (ECOG 2): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.09 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.54 mg/dL; Immunoglobulin G 8.71 g/L; Immunoglobulin A 3.57 g/L; Immunoglobulin M 1.33 g/L; Lactate Dehydrogenase 3.23 µkat/L; Hemoglobin 7.5 mmol/L; Leukocytes 12 ×10⁹/L; Absolute Neutrophil 9 ×10⁹/L; Platelets 308 ×10⁹/L; Creatinine 117 µmol/L; Blood Urea Nitrogen 12.1 mmol/L; Calcium 2.38 mmol/L; Albumin 41 g/L; Total Protein 7 g/dL; Glucose 14.6 mmol/L.
- Day 1,271 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.24 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.53 mg/dL; Immunoglobulin G 9.03 g/L; Immunoglobulin A 4.28 g/L; Immunoglobulin M 1.81 g/L; Lactate Dehydrogenase 2.83 µkat/L; Hemoglobin 8.37 mmol/L; Leukocytes 10.8 ×10⁹/L; Absolute Neutrophil 7.9 ×10⁹/L; Platelets 253 ×10⁹/L; Creatinine 101 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.4 mmol/L; Albumin 40 g/L; Total Protein 7.4 g/dL; Glucose 15.8 mmol/L.
- Day 1,362 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.69 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.48 mg/dL; Immunoglobulin G 8.62 g/L; Immunoglobulin A 4.3 g/L; Immunoglobulin M 1.94 g/L; Lactate Dehydrogenase 2.58 µkat/L; Hemoglobin 8.37 mmol/L; Leukocytes 10.8 ×10⁹/L; Absolute Neutrophil 8.1 ×10⁹/L; Platelets 261 ×10⁹/L; Creatinine 126 µmol/L; Blood Urea Nitrogen 12.5 mmol/L; Calcium 2.4 mmol/L; Albumin 43 g/L; Total Protein 7.4 g/dL; Glucose 12.1 mmol/L.

Other clinical attributes
- Day -14: Weight: 92 kg; Height: 160 cm.

Family history
- Relative with cancer history: yes; Relationship type: Father; Relationship sex at birth: male.
- Relative with cancer history: yes; Relationship type: Sibling.

Biospecimens (2 samples)
- Sample MMRF_1423_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -14 days.
- Sample MMRF_1423_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -14 days.
